Somatic mutation profile of tumor specimen TCGA-AF-4110-01A (aliquot TCGA-AF-4110-01A-02D-1733-10) from TCGA case TCGA-AF-4110, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVA; Age at diagnosis: 77.5 years (28,289 days).
Specimen TCGA-AF-4110-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5da3a04a-ebff-435d-9443-10d973476bd3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AF-4110-10A (Blood Derived Normal), aliquot TCGA-AF-4110-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e64e1a4-534d-41f9-8e36-efd65f4714e7

The open-access MAF lists 105 somatic variants for this specimen: 76 protein-altering or splice-affecting, 29 silent.
By variant classification: Missense Mutation 67, Silent 29, Nonsense Mutation 4, Frame Shift Ins 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 12/47 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.5975C>T p.A1992V (on ENST00000614293; = p.A1962V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.919); catalogued as COSV99687144; called by muse, mutect2, varscan2
- ABCF1 | c.1997C>T p.T666M (on ENST00000326195 / NM_001025091.2; = p.T628M on NM_001090.3) | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100400757; called by muse, mutect2
- AFAP1L1 | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs760661630, COSV57043750; called by muse, mutect2, varscan2
- AKAP9 | c.10100A>G p.D3367G (on ENST00000359028; = p.D3343G on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as COSV100662091; called by muse, mutect2, varscan2
- ANKRD11 | c.6535G>A p.V2179I | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV56354544; called by muse, mutect2, varscan2
- APC | c.1624C>T p.Q542* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as CM071554, COSV57324072; called by muse, mutect2, varscan2
- APC | c.3980C>A p.S1327* | Nonsense Mutation (SNP) | VAF 38/132 reads (29%) | catalogued as COSV57323640, COSV57335489, COSV57371230; called by muse, mutect2, varscan2
- APOBEC3G | c.902A>C p.K301T | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as COSV101349051; called by muse, mutect2, varscan2
- BCL9 | c.371-1G>T p.X124_splice | Splice Site (SNP) | VAF 14/73 reads (19%) | catalogued as COSV52340830; called by muse, mutect2, varscan2
- CABIN1 | c.3065C>A p.P1022Q | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99572865; called by muse, mutect2
- CACNA1H | c.4835C>T p.S1612L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs370292995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CADM2 | c.970A>G p.T324A (on ENST00000407528 / NM_001167674.2; = p.T326A on NM_153184.4) | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs1333801205, COSV101052639; called by muse, mutect2, varscan2
- CAMK4 | c.1184T>C p.M395T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV56661908; called by muse, mutect2
- CDR1 | c.675A>T p.R225S | Missense Mutation (SNP) | VAF 84/142 reads (59%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as COSV65163828; called by muse, mutect2, varscan2
- COL1A2 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381927942, COSV99798933; called by muse, mutect2, varscan2
- CPT1C | c.1502G>A p.C501Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54917478; called by muse, mutect2, varscan2
- CSF3R | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV100117427; called by muse, mutect2, varscan2
- DAAM2 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs775379327, COSV51302090; called by muse, mutect2, varscan2
- DCLK1 | c.1699A>T p.K567* | Nonsense Mutation (SNP) | VAF 11/94 reads (12%) | catalogued as COSV55171093; called by muse, mutect2, varscan2
- DHX34 | c.944A>G p.N315S | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60894348; called by muse, mutect2, varscan2
- DIP2A | c.4309C>T p.R1437W | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1171788823, COSV59471378; called by muse, mutect2, varscan2
- DSPP | c.1031C>A p.T344N | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); catalogued as rs767387863, COSV99216769; ClinVar: likely benign; called by muse, mutect2, varscan2
- EP400 | c.8903G>A p.G2968D | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV57762410; called by muse, mutect2, varscan2
- ERBB4 | c.2701A>T p.S901C | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100724055; called by muse, mutect2, varscan2
- FBN1 | c.3929G>A p.G1310D | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM077262, CM099390, COSV57309044; called by muse, mutect2, varscan2
- FGD5 | c.3290T>C p.I1097T | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs745344599, COSV53237031; called by muse, mutect2, varscan2
- FITM1 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV99246101; called by muse, mutect2, varscan2
- FLT1 | c.3244G>A p.V1082M | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142586121; called by muse, mutect2, varscan2
- IGSF22 | c.2069C>T p.T690M | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as rs766055265, COSV60030653; called by muse, mutect2, varscan2
- ILKAP | c.569G>C p.C190S | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.086); catalogued as COSV54517328; called by muse, mutect2, varscan2
- IMPG1 | c.584G>C p.G195A | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV64054137; called by muse, mutect2, varscan2
- INA | c.1141G>T p.D381Y | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63975542; called by muse, mutect2, varscan2
- IQGAP2 | c.304-1G>C p.X102_splice | Splice Site (SNP) | VAF 35/148 reads (24%) | catalogued as COSV57167653; called by muse, mutect2, varscan2
- KCNA10 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs190117605; called by muse, mutect2, varscan2
- KCNK13 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.014); catalogued as rs369202821, COSV56418467; called by muse, mutect2, varscan2
- KLHL38 | c.457A>G p.K153E | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV58085958; called by muse, mutect2
- KRBA1 | c.1390A>C p.T464P | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.886); catalogued as rs937661422, COSV99752333; called by muse, mutect2, varscan2
- LRRC8D | c.2308C>A p.Q770K | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV61577654; called by muse, mutect2, varscan2
- MDGA2 | c.1340G>A p.R447H (on ENST00000399232 / NM_001113498.2; = p.R149H on NM_182830.4) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs866090116, COSV62078847; called by muse, mutect2, varscan2
- MMP16 | c.209A>G p.Q70R | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV54150681; called by muse, mutect2, varscan2
- MPL | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs769867913, COSV65243985; called by muse, mutect2, varscan2
- MPRIP | c.1599G>T p.E533D | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57925441; called by muse, mutect2, varscan2
- MYO7B | c.4793C>T p.P1598L | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV67344373; called by muse, mutect2, varscan2
- NRAP | c.4346A>G p.K1449R (on ENST00000359988 / NM_001322945.2; = p.K1414R on NM_006175.4) | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV63488413; called by muse, mutect2, varscan2
- NUBP2 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99236408; called by muse, mutect2, varscan2
- ODF2 | c.2462C>G p.P821R (on ENST00000434106 / NM_153433.2; = p.P797R on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV59406216; called by muse, mutect2, varscan2
- PCDH18 | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs777379654, COSV100787113; called by muse, mutect2, varscan2
- PCDH19 | c.3397C>T p.R1133C (on ENST00000373034 / NM_001184880.2; = p.R1085C on NM_020766.3) | Missense Mutation (SNP) | VAF 66/117 reads (56%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.635); catalogued as rs778009939, COSV55257412; called by muse, mutect2, varscan2
- PCDHGB5 | c.1053G>T p.M351I | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1454578078; called by muse, mutect2, varscan2
- PDGFRA | c.1319C>T p.T440M | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs143344944, COSV57265372; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- PLAUR | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV55388400, COSV55389617; called by muse, mutect2, varscan2
- PNLDC1 | c.789C>A p.H263Q | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.478); catalogued as COSV51703690; called by muse, mutect2, varscan2
- POC5 | c.1111C>T p.Q371* (on ENST00000428202 / NM_001099271.2; = p.Q346* on NM_152408.2) | Nonsense Mutation (SNP) | VAF 26/112 reads (23%) | catalogued as COSV62807405; called by muse, mutect2, varscan2
- PPFIA2 | c.2852G>A p.R951H | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61020166; called by muse, mutect2, varscan2
- RABIF | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV66126943; called by muse, mutect2, varscan2
- RP1 | c.2827A>G p.S943G | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99606669; called by mutect2, varscan2
- SLC12A5 | c.1610C>T p.S537L (on ENST00000454036 / NM_001134771.2; = p.S514L on NM_020708.5) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs771520319, COSV54788182; called by muse, mutect2, varscan2
- SLC22A2 | c.909T>G p.I303M | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV65265616; called by muse, mutect2, varscan2
- SLCO1B1 | c.1865C>T p.S622L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.278); catalogued as rs368052440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLITRK5 | c.1795G>C p.A599P | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV61520886, COSV61521204; called by muse, mutect2, varscan2
- SMARCA1 | c.2761C>T p.R921C | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV64410735; called by muse, mutect2, varscan2
- SULF2 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.149); catalogued as rs1309004209, COSV100737062; called by muse, mutect2, varscan2
- TEX15 | c.2448A>C p.E816D (on ENST00000256246; = p.E1199D on NM_001350162.2) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.242); catalogued as COSV56341399; called by muse, mutect2, varscan2
- TP53 | c.654dup p.P219Afs*3 | Frame Shift Ins (INS) | VAF 26/76 reads (34%) | catalogued as COSV52886268; called by mutect2, pindel, varscan2
- TRPV4 | c.2550C>G p.N850K | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as COSV55679719; called by muse, mutect2, varscan2
- TTN | c.39310G>A p.D13104N (on ENST00000591111; = p.D5680N on NM_003319.4) | Missense Mutation (SNP) | VAF 21/125 reads (17%) | PolyPhen benign (0.311); catalogued as COSV59880272; called by muse, mutect2, varscan2
- TUBGCP2 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs763765637, COSV53302663; called by muse, mutect2, varscan2
- UNC79 | c.5189A>T p.E1730V (on ENST00000393151 / NM_001346218.2; = p.E1553V on NM_020818.5) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.143); catalogued as COSV56373259; called by muse, mutect2, varscan2
- ZSCAN5A | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs768639394, COSV54223645; called by mutect2, varscan2
- ZSWIM8 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1421926073, COSV67131066; called by muse, mutect2, varscan2
- BRF2 | c.692dup p.L232Pfs*21 | Frame Shift Ins (INS) | VAF 9/78 reads (12%) | called by mutect2, pindel, varscan2
- MC3R | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- POLR1F | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); called by muse, mutect2
- SH2D4A | c.455A>G p.K152R | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.026); called by muse, mutect2
- TCF7L2 | c.660dup p.P221Tfs*107 (on ENST00000355995 / NM_001367943.1; = p.P198Tfs*107 on NM_030756.5) | Frame Shift Ins (INS) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- ACSL3 | c.705C>A p.I235= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV62480738; called by muse, mutect2, varscan2
- C1QL3 | c.532C>T p.L178= | Silent (SNP) | VAF 10/125 reads (8%) | catalogued as COSV54348108; called by muse, mutect2
- COL27A1 | c.1290G>A p.P430= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs201849595, COSV100620774; called by muse, mutect2, varscan2
- DNAH7 | c.11406G>A p.S3802= | Silent (SNP) | VAF 28/270 reads (10%) | catalogued as rs765905199, COSV56776875; called by muse, varscan2
- DSEL | c.1092T>C p.N364= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV59489394; called by muse, mutect2, varscan2
- EPB41L1 | c.414C>T p.F138= | Silent (SNP) | VAF 48/78 reads (62%) | catalogued as rs373620188; called by muse, mutect2, varscan2
- FAM71F1 | c.504A>G p.T168= | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as COSV59372807; called by muse, mutect2, varscan2
- FASN | c.3573C>T p.N1191= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as rs758512736, COSV60750331; called by muse, mutect2, varscan2
- FCER2 | c.885T>C p.G295= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV100689521; called by muse, mutect2, varscan2
- GRAMD2B | c.1272A>G p.L424= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV53505752; called by muse, mutect2, varscan2
- H2BC12 | c.15G>A p.A5= | Silent (SNP) | VAF 56/128 reads (44%) | catalogued as COSV100804594, COSV63616948; called by muse, mutect2, varscan2
- HACD3 | c.339A>G p.E113= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV56010765; called by muse, mutect2, varscan2
- IGHV3-16 | c.321C>T p.A107= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs782451154; called by muse, mutect2, varscan2
- IGKV1-17 | c.255C>T p.S85= | Silent (SNP) | VAF 62/219 reads (28%) | catalogued as rs749048857; called by muse, mutect2, varscan2
- INTS1 | c.3552C>T p.S1184= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs781722828, COSV67176314; called by muse, mutect2, varscan2
- KIAA1549 | c.3027G>T p.T1009= | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as COSV54305302, COSV99651592; called by muse, mutect2, varscan2
- MARCHF10 | c.507T>A p.P169= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as COSV60885061; called by muse, mutect2, varscan2
- MEP1A | c.717C>T p.I239= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as rs146158038; called by muse, mutect2, varscan2
- MFSD4A | c.615G>A p.T205= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs780616570, COSV65655971; called by muse, mutect2, varscan2
- MKI67 | c.3964C>T p.L1322= | Silent (SNP) | VAF 114/395 reads (29%) | catalogued as COSV64072458; called by muse, mutect2, varscan2
- NFKBIE | c.108C>T p.A36= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV51487454; called by muse, mutect2
- NRBP1 | c.1554C>T p.F518= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV51993057; called by muse, mutect2, varscan2
- PCED1B | c.834G>A p.P278= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs752317404, COSV71394863; called by muse, mutect2, varscan2
- PNLIPRP2 | c.186A>G p.E62= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV53942039; called by muse, mutect2, varscan2
- PPP2R5C | c.1005C>T p.V335= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV58268187; called by muse, mutect2, varscan2
- TTN | c.27G>A p.T9= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs760305568, COSV59880306; ClinVar: likely benign; called by muse, mutect2, varscan2
- VPS37C | c.231C>T p.L77= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs763115048, COSV57107914; called by muse, mutect2, varscan2
- ZNF407 | c.6300C>T p.D2100= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs527541602, COSV55242232; called by muse, mutect2, varscan2
- ZNF646 | c.4149G>A p.L1383= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV54922569; called by muse, mutect2, varscan2
